Somatic mutation profile of tumor specimen C3N-03918-01 (aliquot CPT0248690006) from CPTAC case C3N-03918, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.4 years (29,353 days).
Specimen C3N-03918-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f7fb6fa-aae3-498b-8563-b433ae17c5dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03918-71 (Blood Derived Normal), aliquot CPT0248810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbbbfa3c-cce0-4efd-8a40-5ae5b64c1c5e

The open-access MAF lists 913 somatic variants for this specimen: 599 protein-altering or splice-affecting, 281 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 538, Silent 281, Nonsense Mutation 38, Intron 20, Splice Region 14, 3'UTR 5, Splice Site 5, 5'Flank 4, Frame Shift Del 3, 3'Flank 2, RNA 2, In Frame Ins 1.

Variants (750 of 913; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367916692, CM092982, CM114726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 107/375 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs1057519729, COSV61068787; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCSK5 | c.2772G>A p.W924* | Nonsense Mutation (SNP) | VAF 112/390 reads (29%) | hotspot (GDC flag); catalogued as rs1170804599, COSV70449546; called by muse, mutect2, varscan2
- SPINK5 | c.2557C>T p.R853* | Nonsense Mutation (SNP) | VAF 81/304 reads (27%) | catalogued as rs753621591, CM121226, COSV56252267; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 161/369 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs574044306, COSV50966965; called by muse, mutect2, varscan2
- ACTB | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 254/712 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV59321436; called by muse, mutect2, varscan2
- ADAM21 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 129/430 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV50807533; called by muse, mutect2, varscan2
- ADAT1 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749428527; called by muse, mutect2, varscan2
- ADCK5 | c.1226A>C p.D409A | Missense Mutation (SNP) | VAF 69/1004 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as rs782208902, COSV58233174; called by muse, mutect2
- ADGRG4 | c.3797G>A p.G1266E | Missense Mutation (SNP) | VAF 167/609 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs748033473, COSV54955639; called by muse, mutect2, varscan2
- ADGRV1 | c.14305G>A p.D4769N | Missense Mutation (SNP) | VAF 161/524 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV67979006; called by muse, mutect2, varscan2
- AGL | c.3919C>T p.P1307S | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54060706; called by muse, mutect2, varscan2
- ALDH1B1 | c.56A>C p.Y19S | Missense Mutation (SNP) | VAF 150/515 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.079); catalogued as COSV100890945; called by muse, mutect2, varscan2
- AMPD3 | c.877G>A p.E293K (on ENST00000396553 / NM_001025389.2; = p.E302K on NM_000480.3) | Missense Mutation (SNP) | VAF 104/354 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs760590808, COSV67331501; called by muse, mutect2, varscan2
- AMY2A | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 107/400 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101340674; called by muse, mutect2, varscan2
- AMY2A | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs1432363996; called by mutect2, varscan2
- APOL6 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 142/507 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV68749804; called by muse, mutect2, varscan2
- ARHGEF5 | c.3661C>T p.R1221C | Missense Mutation (SNP) | VAF 50/533 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769482772, COSV99282465, COSV99282618; called by muse, mutect2, varscan2
- ATCAY | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 145/491 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100009089; called by muse, mutect2, varscan2
- BAZ2B | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as COSV58609804; called by muse, mutect2, varscan2
- BBS4 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 132/423 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs762950416; called by muse, mutect2, varscan2
- BRD1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 183/625 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138141016; called by muse, mutect2, varscan2
- C10orf120 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 136/343 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as rs868856614, COSV61491793, COSV61492605; called by muse, mutect2, varscan2
- C3 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 129/450 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV55569722; called by muse, mutect2, varscan2
- C7 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs1056448422, COSV100496490; called by muse, mutect2, varscan2
- CACNA1A | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 229/690 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.113); catalogued as rs780879206; called by muse, mutect2, varscan2
- CALCOCO1 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 147/521 reads (28%) | catalogued as rs753475661; called by muse, mutect2, varscan2
- CAPN9 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438995172; called by muse, mutect2, varscan2
- CCDC124 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 92/390 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71490558; called by muse, mutect2, varscan2
- CCDC141 | c.4109C>T p.S1370L | Missense Mutation (SNP) | VAF 127/401 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs757976968; called by muse, mutect2, varscan2
- CCDC178 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as COSV100285616, COSV55761980; called by muse, mutect2, varscan2
- CCDC181 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as rs773563534, COSV63156807; called by muse, mutect2, varscan2
- CCT6B | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs767958063, COSV58490674; called by muse, mutect2, varscan2
- CD177 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 141/518 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs1322809715; called by muse, mutect2, varscan2
- CDH4 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 99/363 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64640868; called by muse, mutect2, varscan2
- CFAP69 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 175/539 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs375665829, COSV60185206; called by muse, mutect2, varscan2
- CFH | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 107/399 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.322); catalogued as rs867229260, COSV66406054; called by muse, mutect2, varscan2
- CFHR5 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 109/384 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs890060392, COSV56819542; called by muse, mutect2, varscan2
- CHAMP1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 149/519 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1490070176, COSV63522321; called by muse, mutect2, varscan2
- CHGB | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV66761358; called by muse, mutect2, varscan2
- CHL1 | c.925C>T p.R309C (on ENST00000397491 / NM_001253387.1; = p.R325C on NM_006614.4) | Missense Mutation (SNP) | VAF 141/504 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs769936753; called by muse, mutect2, varscan2
- CLCA1 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 115/451 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as rs1380358173, COSV52327888; called by muse, mutect2, varscan2
- CLDN19 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 135/474 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1279949075; called by muse, mutect2, varscan2
- CNMD | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 138/445 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1203275405; called by muse, mutect2, varscan2
- CNTN4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 120/388 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018920181, COSV61867465; called by muse, varscan2
- CNTN6 | c.1865C>A p.P622Q | Missense Mutation (SNP) | VAF 105/405 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV100611964; called by muse, mutect2, varscan2
- COL11A1 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 109/401 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV62196469; called by muse, mutect2, varscan2
- COL5A1 | c.3304G>A p.G1102R | Missense Mutation (SNP) | VAF 158/525 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65668809; called by muse, mutect2, varscan2
- COL5A3 | c.4181G>A p.G1394E | Missense Mutation (SNP) | VAF 133/524 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99319986; called by muse, mutect2, varscan2
- COL5A3 | c.4180G>A p.G1394R | Missense Mutation (SNP) | VAF 133/527 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV53412332; called by muse, mutect2, varscan2
- COL6A5 | c.2327G>A p.G776E | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55208390, COSV99593837; called by muse, mutect2, varscan2
- COL8A2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 230/654 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV57441142; called by muse, mutect2, varscan2
- CPD | c.2962C>T p.R988C | Missense Mutation (SNP) | VAF 129/473 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760977698, COSV56711796; called by muse, mutect2, varscan2
- CPZ | c.1192G>A p.E398K (on ENST00000360986 / NM_001014447.3; = p.E387K on NM_003652.3) | Missense Mutation (SNP) | VAF 129/436 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as rs1560296190, COSV59923651; called by muse, mutect2, varscan2
- CRB2 | c.3709C>T p.L1237F | Missense Mutation (SNP) | VAF 167/656 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs373603388; called by muse, mutect2, varscan2
- CRIM1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 119/436 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as rs1353365524; called by muse, mutect2, varscan2
- CYP21A2 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 385/913 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs770843305, CD057025; called by muse, mutect2, varscan2
- CYP2C18 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 127/320 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142667327, COSV53674528; called by muse, mutect2, varscan2
- CYP4X1 | c.1209G>A p.G403= | Splice Region (SNP) | VAF 75/294 reads (26%) | catalogued as COSV64150780; called by muse, mutect2, varscan2
- DES | c.1038G>A p.M346I | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as rs778340812; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKG | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 140/332 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961769; called by muse, mutect2, varscan2
- DLGAP5 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 123/410 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs372521527, COSV55962857; called by muse, mutect2, varscan2
- DNAH10 | c.13138G>A p.E4380K (on ENST00000409039; = p.E4319K on NM_207437.3) | Missense Mutation (SNP) | VAF 149/503 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1476443729; called by muse, mutect2, varscan2
- DNAH3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 137/426 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866756868; called by muse, mutect2, varscan2
- DOCK3 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 108/298 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56549182; called by muse, mutect2, varscan2
- DPYS | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs751818026, COSV60907008; called by muse, mutect2, varscan2
- DSC2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV51863565, COSV99199653; called by muse, mutect2, varscan2
- DSEL | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 163/561 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as rs750896094; called by muse, mutect2, varscan2
- DSG1 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV57138246; called by muse, mutect2, varscan2
- DSG4 | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 146/497 reads (29%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.973); catalogued as rs1220004874; called by muse, mutect2, varscan2
- DSP | c.6478C>T p.R2160* | Nonsense Mutation (SNP) | VAF 81/547 reads (15%) | catalogued as rs777573018, CM136693; called by muse, mutect2, varscan2
- DUSP8 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as rs1320691815; called by muse, mutect2, varscan2
- DUSP8 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 167/614 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV100524388; called by muse, mutect2, varscan2
- DYRK4 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 120/466 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs755664062, COSV50538391; called by muse, mutect2, varscan2
- EMILIN3 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 191/598 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776502404; called by muse, mutect2, varscan2
- ERC2 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 129/471 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs866470365, COSV55609221, COSV55611425; called by muse, mutect2, varscan2
- EXD1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs775248112, COSV59257064; called by muse, mutect2, varscan2
- EXD1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 136/490 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1410821939; called by muse, mutect2, varscan2
- F13B | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100803265; called by muse, mutect2, varscan2
- FAIM2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs967151883; called by muse, mutect2, varscan2
- FBLN2 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 137/574 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99851700; called by muse, mutect2, varscan2
- FBRSL1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 157/553 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs958493558; called by muse, mutect2, varscan2
- FCRL1 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 65/346 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV63825403; called by muse, mutect2, varscan2
- FCRL1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 121/401 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754736511, COSV63825819; called by muse, mutect2, varscan2
- FGB | c.833-1G>A p.X278_splice | Splice Site (SNP) | VAF 77/268 reads (29%) | catalogued as COSV57418688; called by muse, mutect2, varscan2
- FLG | c.11449G>A p.E3817K | Missense Mutation (SNP) | VAF 164/648 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as rs757686514; called by muse, mutect2, varscan2
- FLT3 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs866313760; called by muse, mutect2, varscan2
- FLYWCH1 | c.1841C>T p.S614F (on ENST00000253928 / NM_001308068.2; = p.S613F on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/456 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54143092; called by muse, mutect2, varscan2
- FMN2 | c.3013G>A p.G1005R | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.971); catalogued as rs534635159, COSV100147174, COSV60430473; called by muse, mutect2, varscan2
- FMN2 | c.3715C>T p.P1239S | Missense Mutation (SNP) | VAF 130/538 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.977); catalogued as rs1367043984, COSV60422634; called by muse, mutect2, varscan2
- FOXB2 | c.782C>A p.A261E | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV100942373; called by muse, mutect2, varscan2
- FOXI2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 139/400 reads (35%) | catalogued as rs762129101; called by muse, mutect2, varscan2
- FRAS1 | c.3371C>T p.S1124F | Missense Mutation (SNP) | VAF 119/481 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV53591666; called by muse, mutect2
- FREM3 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 137/516 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467561521; called by muse, mutect2, varscan2
- FUT9 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 106/355 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs1470703687, COSV100134322, COSV56143911; called by muse, mutect2, varscan2
- GABRE | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 168/617 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs757646574, COSV64818761, COSV64819994, COSV64821147; called by muse, mutect2, varscan2
- GARNL3 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 91/363 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV59230859; called by muse, mutect2, varscan2
- GAS2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53407324; called by muse, mutect2, varscan2
- GBP5 | c.1451A>G p.E484G | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1463198595; called by muse, mutect2, varscan2
- GDNF | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs574185638; called by muse, mutect2, varscan2
- GLP2R | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 148/517 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.108); catalogued as COSV52329260; called by muse, mutect2, varscan2
- GNB4 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV51709105; called by muse, mutect2, varscan2
- GPR50 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 149/470 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54442736; called by muse, mutect2, varscan2
- GPRC6A | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 118/438 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99055482; called by muse, mutect2, varscan2
- GPRIN2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 143/786 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs374560306; called by muse, mutect2, varscan2
- GREB1L | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1274267669, COSV52555332; called by muse, mutect2, varscan2
- GRIA1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.281); catalogued as rs1335115184, COSV53594707; called by muse, mutect2, varscan2
- GRIN2A | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 186/603 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.482); catalogued as rs1200593226, COSV58026502, COSV58058380; called by muse, mutect2, varscan2
- GRIN3A | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 160/627 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs867334369, COSV62450515; called by muse, mutect2, varscan2
- GRM1 | c.2273G>A p.G758D | Missense Mutation (SNP) | VAF 133/522 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99264232; called by muse, mutect2, varscan2
- GRM3 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 233/710 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.37); catalogued as COSV100862672, COSV64481178; called by muse, mutect2, varscan2
- GSTCD | c.1798C>T p.R600* (on ENST00000360505 / NM_001031720.3; = p.R513* on NM_024751.3) | Nonsense Mutation (SNP) | VAF 138/418 reads (33%) | catalogued as rs375779179; called by muse, mutect2, varscan2
- GXYLT1 | c.612G>A p.P204= | Splice Region (SNP) | VAF 51/188 reads (27%) | catalogued as rs532923494; called by muse, mutect2, varscan2
- HCN1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV99079144; called by muse, mutect2, varscan2
- HOXB1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 138/514 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567932264; ClinVar: uncertain significance; called by muse, varscan2
- HS6ST2 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 174/600 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63711974; called by muse, mutect2, varscan2
- HTR1F | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs183674304; called by muse, mutect2, varscan2
- HTR3A | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 109/378 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs886296854, COSV55467853; called by muse, mutect2, varscan2
- HTR3B | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 130/454 reads (29%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.998); catalogued as COSV52743560; called by muse, mutect2, varscan2
- HTR5A | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 282/735 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs746290830, COSV55285522, COSV99839814; called by muse, mutect2, varscan2
- IFNA4 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 144/569 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV101427089; called by muse, mutect2, varscan2
- IKZF1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 199/575 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100498544; called by muse, mutect2, varscan2
- IQCA1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs577893508, COSV54499248; called by muse, mutect2, varscan2
- ITGA9 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV53249564; called by muse, mutect2, varscan2
- ITGAM | c.1822G>A p.G608R (on ENST00000648685 / NM_001145808.2; = p.G607R on NM_000632.4) | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1567278012, COSV54944467; called by muse, mutect2, varscan2
- ITGB6 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 113/437 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750398020, COSV51790735, COSV51795910; called by muse, mutect2, varscan2
- JMY | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs778673068, COSV68660549; called by muse, mutect2, varscan2
- KANK4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 134/545 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs201256809, COSV62985569; called by muse, mutect2, varscan2
- KCNB1 | c.570C>T p.I190= | Splice Region (SNP) | VAF 63/256 reads (25%) | catalogued as COSV65570181; called by muse, mutect2, varscan2
- KCNJ1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 162/554 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758505864, CM117812; called by muse, mutect2, varscan2
- KCNN1 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 207/622 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs868614193, COSV55837393; called by muse, mutect2, varscan2
- KLHL40 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs760884994; called by muse, mutect2, varscan2
- KRT6C | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 106/408 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV52878914; called by muse, varscan2
- LGALS9 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 141/493 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1567917015, COSV56351678; called by muse, mutect2, varscan2
- LIMCH1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149800400, COSV58292524; called by muse, varscan2
- LRRC66 | c.114G>A p.W38* | Nonsense Mutation (SNP) | VAF 97/332 reads (29%) | catalogued as rs866814875; called by muse, mutect2, varscan2
- LRRK1 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 115/366 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs773225777, COSV52607733; called by muse, mutect2, varscan2
- LTBP2 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 187/648 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1310944162; called by muse, mutect2, varscan2
- LVRN | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 95/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV63495922; called by muse, mutect2, varscan2
- LY6K | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); catalogued as rs868963723; called by muse, mutect2
- MAGEA3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 221/659 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs782715078, COSV100938978, COSV100939016; called by muse, mutect2, varscan2
- MAGEC2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 173/687 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV55997948; called by muse, mutect2, varscan2
- MBOAT4 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 137/497 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs146255946, COSV57642281; called by muse, mutect2, varscan2
- MCHR2 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs201703300, COSV56004382; called by muse, mutect2, varscan2
- MFSD10 | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 126/405 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201068903, COSV53266000; called by muse, mutect2, varscan2
- MKS1 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 103/372 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201036775; called by muse, mutect2, varscan2
- MMP16 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 123/554 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as COSV99690787; called by muse, mutect2, varscan2
- MMUT | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 128/467 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs373381232; called by muse, mutect2, varscan2
- MTMR8 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 185/659 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.057); catalogued as COSV66395772; called by muse, mutect2, varscan2
- MUC12 | c.13703C>T p.P4568L (on ENST00000379442; = p.P4425L on NM_001164462.1) | Missense Mutation (SNP) | VAF 362/1155 reads (31%) | SIFT deleterious (0); catalogued as rs1202570072; called by muse, mutect2, varscan2
- MUC16 | c.17215G>A p.D5739N | Missense Mutation (SNP) | VAF 131/484 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.263); catalogued as COSV67486167; called by muse, mutect2, varscan2
- MUC16 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 116/383 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV67467612; called by muse, mutect2, varscan2
- MUC4 | c.16136G>A p.G5379D (on ENST00000463781 / NM_018406.7; = p.G1143D on NM_004532.6) | Missense Mutation (SNP) | VAF 221/1246 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1337535264, COSV100206001; called by muse, mutect2
- MXRA5 | c.4907C>T p.S1636F | Missense Mutation (SNP) | VAF 210/739 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754940257; called by muse, mutect2, varscan2
- MXRA5 | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 194/645 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as COSV54224599, COSV54230035; called by muse, mutect2, varscan2
- MYH4 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781091968, COSV55112713; called by muse, mutect2, varscan2
- NAV1 | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs778200308; called by muse, mutect2, varscan2
- NBEA | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV59763242; called by muse, mutect2, varscan2
- NEK8 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 116/496 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs199853008; called by muse, mutect2
- NETO1 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868861139, COSV55007105; called by muse, mutect2, varscan2
- NEXMIF | c.2821G>A p.G941S | Missense Mutation (SNP) | VAF 181/675 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99281450; called by muse, mutect2, varscan2
- NISCH | c.2073A>T p.E691D | Missense Mutation (SNP) | VAF 166/620 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs756789102; called by muse, varscan2
- NKG7 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 171/538 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1568477043; called by muse, mutect2, varscan2
- NLRP2 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 175/686 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as rs572832021, COSV54753648; called by muse, mutect2, varscan2
- NME8 | c.198C>T p.V66= | Splice Region (SNP) | VAF 122/325 reads (38%) | catalogued as rs748684004, COSV52250302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOD1 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 369/1041 reads (35%) | catalogued as rs747599714; called by muse, mutect2, varscan2
- NOS1 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 131/405 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs769811727, COSV57609906; called by muse, mutect2, varscan2
- NOS1 | c.1524G>A p.E508= | Splice Region (SNP) | VAF 92/327 reads (28%) | catalogued as COSV57611917, COSV57623629; called by muse, mutect2, varscan2
- NPAP1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 150/521 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.172); catalogued as COSV61504791; called by muse, mutect2, varscan2
- NPY2R | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 142/452 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as COSV61528479; called by muse, mutect2, varscan2
- NWD2 | c.4687G>A p.A1563T | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.985); catalogued as rs200088519; called by muse, mutect2, varscan2
- OPRK1 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV55572893; called by muse, mutect2, varscan2
- OPTC | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV100921840; called by muse, mutect2, varscan2
- OR10A6 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 130/413 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59164478; called by muse, mutect2, varscan2
- OR10S1 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 167/591 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV73343097; called by muse, mutect2
- OR13C8 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 104/395 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58612259; called by muse, mutect2, varscan2
- OR2A12 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 244/727 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV101283204; called by muse, mutect2, varscan2
- OR2B3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 391/1110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV65851221; called by muse, mutect2, varscan2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 109/416 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by muse, mutect2, varscan2
- OR2M7 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 178/581 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs756006276, COSV58740798; called by muse, mutect2, varscan2
- OR4D5 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 166/598 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV58307304; called by muse, mutect2, varscan2
- OR52E1 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 111/410 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs778124851; called by muse, mutect2, varscan2
- OR5P2 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 109/411 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs142490724, COSV61490067; called by muse, mutect2, varscan2
- OR5T3 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 149/598 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs368667732; called by muse, mutect2, varscan2
- OR8B12 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 121/510 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV60911416; called by muse, mutect2, varscan2
- OSBPL10 | c.1977G>T p.W659C | Missense Mutation (SNP) | VAF 118/471 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67339628; called by muse, mutect2, varscan2
- OVCH2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 98/319 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs773982264, COSV71952995; called by muse, mutect2, varscan2
- P2RY8 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 167/602 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1569536194; called by muse, mutect2, varscan2
- PCDHA3 | c.2288G>A p.G763E | Missense Mutation (SNP) | VAF 140/543 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1562194526; called by muse, mutect2, varscan2
- PCDHB4 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 142/483 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52020391, COSV52026805; called by muse, mutect2, varscan2
- PCDHGB5 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 118/431 reads (27%) | catalogued as rs749773693; called by muse, mutect2, varscan2
- PCDHGC4 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 164/541 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.288); catalogued as COSV52747357; called by muse, mutect2, varscan2
- PDE7B | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV100368572; called by muse, mutect2, varscan2
- PFKFB1 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 106/403 reads (26%) | PolyPhen benign (0.014); catalogued as COSV100895837; called by muse, mutect2, varscan2
- PGLYRP3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 98/358 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1426979746, COSV99319793; called by muse, mutect2, varscan2
- PGR | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 176/594 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV54807869; called by muse, mutect2
- PHF24 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 110/396 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as rs768314962; called by muse, mutect2, varscan2
- PIK3R5 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 128/506 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775810359, COSV52652004; called by muse, mutect2, varscan2
- PLCZ1 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 109/378 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV56852718; called by muse, mutect2, varscan2
- PLEKHA7 | c.2674C>T p.R892* | Nonsense Mutation (SNP) | VAF 186/652 reads (29%) | catalogued as COSV100262023; called by muse, mutect2, varscan2
- POLR3A | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64932084; called by muse, varscan2
- POLRMT | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 150/486 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); catalogued as rs1309159241; called by muse, mutect2, varscan2
- POTEG | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs1448170585; called by mutect2, varscan2
- PPME1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 78/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60295890; called by muse, mutect2, varscan2
- PPP1R9A | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 196/543 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99196124; called by muse, mutect2, varscan2
- PRR27 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 99/373 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs766217684, COSV100748870, COSV60641441; called by muse, mutect2, varscan2
- PRSS56 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 180/588 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as rs866637365; called by muse, mutect2, varscan2
- PSMD2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59531757; called by muse, mutect2, varscan2
- PTGFR | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 130/527 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66115028; called by muse, mutect2, varscan2
- PTPN9 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 155/585 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as rs1291261300; called by muse, mutect2, varscan2
- PTPRQ | c.4414C>T p.P1472S (on ENST00000616559; = p.P1430S on NM_001145026.2) | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57044314; called by muse, mutect2, varscan2
- PXDN | c.4211A>G p.K1404R | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.034); catalogued as rs1387447014; called by muse, mutect2, varscan2
- RBM10 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 194/639 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100238413; called by muse, mutect2, varscan2
- RBMXL3 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 197/679 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1450603474, COSV57746775; called by muse, mutect2, varscan2
- REG4 | c.218T>C p.L73S | Missense Mutation (SNP) | VAF 148/480 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as rs377287370; called by muse, mutect2, varscan2
- REPS2 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 131/431 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746046022; called by muse, mutect2, varscan2
- RESF1 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV57022177; called by muse, mutect2, varscan2
- RFX4 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 72/311 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.905); catalogued as rs1259924867, COSV100774337, COSV63504215; called by muse, mutect2, varscan2
- RGS13 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 95/333 reads (29%) | catalogued as COSV67346209; called by muse, mutect2, varscan2
- RGS9 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752804159; called by muse, mutect2, varscan2
- RIPOR3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.54); catalogued as rs772627917; called by muse, mutect2, varscan2
- RNASE9 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 133/482 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs779466707, COSV58881260; called by muse, mutect2, varscan2
- RNF152 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 150/544 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as COSV57186959; called by muse, mutect2, varscan2
- RP1 | c.3289G>A p.G1097S | Missense Mutation (SNP) | VAF 161/546 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55109573; called by muse, mutect2, varscan2
- RP1L1 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 193/727 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs868466461, COSV66752638; called by muse, mutect2, varscan2
- RPLP0 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 150/537 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs867408911; called by muse, mutect2, varscan2
- RUBCNL | c.1745A>G p.D582G | Missense Mutation (SNP) | VAF 127/447 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1202396930; called by muse, mutect2, varscan2
- RYR3 | c.11763A>T p.L3921F (on ENST00000389232; = p.L3922F on NM_001036.6) | Missense Mutation (SNP) | VAF 120/389 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.362); catalogued as rs1051581317; called by muse, mutect2, varscan2
- SCN3A | c.3997C>T p.P1333S | Missense Mutation (SNP) | VAF 85/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866967490; called by muse, mutect2, varscan2
- SCN4A | c.2587G>A p.G863R | Missense Mutation (SNP) | VAF 139/497 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as rs752706137; called by muse, mutect2, varscan2
- SDK2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 114/463 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV66181911; called by muse, mutect2, varscan2
- SELENBP1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 118/417 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64372872; called by muse, mutect2, varscan2
- SERPINB3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 133/558 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV52189892; called by muse, mutect2, varscan2
- SGCZ | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs779373740, COSV65994471; called by muse, mutect2, varscan2
- SH2D1B | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV63392299; called by muse, mutect2, varscan2
- SIM1 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 125/431 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs149142065; called by muse, mutect2, varscan2
- SIX4 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 118/461 reads (26%) | catalogued as COSV53668836, COSV99382087; called by muse, mutect2, varscan2
- SLC12A8 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.149); catalogued as rs1264761915; called by muse, mutect2, varscan2
- SLC14A2 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 102/452 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751258587, COSV54906354; called by muse, mutect2, varscan2
- SLC16A2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 34/894 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52089848; called by muse, mutect2
- SLC17A2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 134/711 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55353359; called by muse, mutect2, varscan2
- SLC17A3 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 76/501 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1561855738; called by muse, mutect2, varscan2
- SLC22A1 | c.1209C>G p.I403M | Missense Mutation (SNP) | VAF 158/509 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV61454331; called by muse, mutect2, varscan2
- SLC34A2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 153/549 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65942867; called by muse, mutect2, varscan2
- SLC35F4 | c.1465G>A p.E489K (on ENST00000339762 / NM_001352015.2; = p.E453K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/470 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV60264354; called by muse, mutect2, varscan2
- SLC6A11 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54390059; called by muse, mutect2, varscan2
- SLC9B1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs778886640; called by muse, mutect2, varscan2
- SLFN14 | c.2726G>A p.R909K | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV70570634; called by muse, mutect2, varscan2
- SLIT3 | c.3974C>T p.S1325F | Missense Mutation (SNP) | VAF 196/659 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV60605450; called by muse, mutect2, varscan2
- SLITRK2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 215/704 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59422686; called by muse, varscan2
- SMAD1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 147/493 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1247730282; called by muse, mutect2, varscan2
- SNCAIP | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54408480, COSV99749284; called by muse, mutect2, varscan2
- SNRPN | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 106/403 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV57596316, COSV57600128; called by muse, mutect2, varscan2
- SPATA18 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV54642720, COSV54645542; called by muse, mutect2, varscan2
- SPATA7 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 99/349 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs267604078, COSV50415827; called by muse, mutect2, varscan2
- SPEG | c.9034G>A p.E3012K | Missense Mutation (SNP) | VAF 168/601 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772022136; called by muse, mutect2, varscan2
- SPI1 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 192/663 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV57044437; called by muse, mutect2, varscan2
- SRRT | c.2250del p.F750Lfs*32 | Frame Shift Del (DEL) | VAF 276/805 reads (34%) | catalogued as COSV99574158; called by mutect2, pindel, varscan2
- ST6GALNAC5 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 127/450 reads (28%) | PolyPhen benign (0.003); catalogued as COSV59562255; called by muse, mutect2, varscan2
- SUMO4 | c.172A>T p.I58F | Missense Mutation (SNP) | VAF 196/678 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs746911325; called by muse, mutect2
- SUPT5H | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 224/796 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.289); catalogued as rs1180760135; called by muse, mutect2, varscan2
- TBCD | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 90/370 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs757402099; called by muse, mutect2, varscan2
- TCHHL1 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 105/323 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs753099539; called by muse, mutect2, varscan2
- TCIRG1 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 115/332 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746538370; called by muse, mutect2, varscan2
- TG | c.7540G>A p.D2514N | Missense Mutation (SNP) | VAF 239/546 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757815753, COSV55064385; called by muse, mutect2
- TGFBI | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 110/445 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs533509858, COSV59350319; called by muse, mutect2
- TGM4 | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 96/377 reads (25%) | catalogued as COSV56093454; called by muse, mutect2, varscan2
- TLR4 | c.280G>A p.E94K (on ENST00000355622 / NM_138554.5; = p.E54K on NM_003266.4) | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100790693, COSV62922466; called by muse, mutect2, varscan2
- TM4SF5 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 113/413 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99564476, COSV99564724; called by muse, mutect2, varscan2
- TMEM100 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 103/367 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.359); catalogued as COSV101448217, COSV70117897; called by muse, mutect2, varscan2
- TMEM132B | c.2920A>G p.R974G | Missense Mutation (SNP) | VAF 141/495 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs757022543; called by muse, mutect2, varscan2
- TMEM132C | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 135/519 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs867814238, COSV59415649; called by muse, mutect2, varscan2
- TOPAZ1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs1250316718; called by muse, mutect2, varscan2
- TRAV19 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 90/313 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as rs267603933; called by muse, mutect2, varscan2
- TRIM60 | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 100/384 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV61970701; called by muse, mutect2, varscan2
- TRPV5 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 189/508 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs768204513, COSV54688491, COSV54690593; called by muse, mutect2, varscan2
- TSC1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 106/362 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as rs770653972, COSV53770764; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- TTN | c.25649G>A p.G8550E (on ENST00000591111; = p.G7623E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/494 reads (26%) | PolyPhen possibly damaging (0.676); catalogued as rs369142169; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.16888C>T p.P5630S (on ENST00000591111; = p.P4703S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/480 reads (30%) | PolyPhen probably damaging (0.998); catalogued as COSV60346897; called by muse, mutect2, varscan2
- TTN | c.7613G>A p.G2538D (on ENST00000591111; = p.G2492D on NM_003319.4) | Missense Mutation (SNP) | VAF 102/370 reads (28%) | PolyPhen possibly damaging (0.9); catalogued as rs1274574174; called by muse, mutect2, varscan2
- TTN | c.5848C>T p.H1950Y (on ENST00000591111; = p.H1904Y on NM_003319.4) | Missense Mutation (SNP) | VAF 132/467 reads (28%) | PolyPhen benign (0.058); catalogued as COSV100592767; called by muse, mutect2, varscan2
- ULK4 | c.3329C>T p.S1110F | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV57210077; called by muse, mutect2, varscan2
- UNC79 | c.2317C>T p.R773C (on ENST00000393151 / NM_001346218.2; = p.R596C on NM_020818.5) | Missense Mutation (SNP) | VAF 160/598 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs781756182, COSV56376369; called by muse, mutect2, varscan2
- VAV3 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 142/439 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV58386980; called by muse, mutect2, varscan2
- VEGFC | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1304972502; called by muse, mutect2
- VSTM2A | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 213/582 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052613457; called by muse, mutect2, varscan2
- VWA5A | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs267602753; called by muse, mutect2, varscan2
- VWA7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 185/841 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs549248721, COSV63304640; called by muse, mutect2, varscan2
- WDR53 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 148/360 reads (41%) | catalogued as COSV100218044; called by muse, mutect2, varscan2
- XIRP2 | c.2584C>T p.Q862* (on ENST00000628543; = p.Q1037* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 93/378 reads (25%) | catalogued as COSV54707350; called by muse, varscan2
- XIRP2 | c.2659C>T p.Q887* (on ENST00000628543; = p.Q1062* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 84/320 reads (26%) | catalogued as COSV99741563; called by muse, varscan2
- ZBED9 | c.3743C>T p.S1248L | Missense Mutation (SNP) | VAF 307/846 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as COSV71729728; called by muse, mutect2, varscan2
- ZBED9 | c.2950G>A p.V984I | Missense Mutation (SNP) | VAF 299/882 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV71729755; called by muse, mutect2, varscan2
- ZBED9 | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 231/751 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV71729642; called by muse, mutect2
- ZFHX2 | c.5495G>A p.R1832Q | Missense Mutation (SNP) | VAF 193/649 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1031309225; called by muse, mutect2, varscan2
- ZFP2 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 110/440 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV63727208; called by muse, mutect2, varscan2
- ZFYVE26 | c.3655C>T p.L1219F | Missense Mutation (SNP) | VAF 111/409 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61333474; called by muse, mutect2, varscan2
- ZHX2 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 186/890 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100072876; called by muse, mutect2, varscan2
- ZNF175 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 112/432 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1357596887; called by muse, mutect2, varscan2
- ZNF37A | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 137/343 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61072889, COSV99080348; called by muse, mutect2, varscan2
- ZNF418 | c.1819T>C p.F607L | Missense Mutation (SNP) | VAF 137/452 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1398346909; called by muse, mutect2, varscan2
- ZNF488 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 183/409 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs536291384; called by muse, mutect2, varscan2
- ZNF845 | c.2125C>T p.H709Y | Missense Mutation (SNP) | VAF 110/372 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1333870540; called by muse, mutect2, varscan2
- ZNF90 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.984); catalogued as COSV69001758; called by muse, mutect2, varscan2
- ABCA12 | c.7194A>C p.L2398F (on ENST00000272895 / NM_173076.3; = p.L2080F on NM_015657.3) | Missense Mutation (SNP) | VAF 115/420 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA3 | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 145/517 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABCC8 | c.1629C>T p.S543= | Splice Region (SNP) | VAF 72/286 reads (25%) | called by muse, mutect2, varscan2
- ABI3BP | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACACA | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 145/553 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACACA | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 159/613 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACER1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 130/438 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ACTN2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 108/369 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADAMTS6 | c.3058C>T p.P1020S | Missense Mutation (SNP) | VAF 110/424 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADAMTS7 | c.4252G>A p.G1418R | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY1 | c.2329G>A p.G777S | Missense Mutation (SNP) | VAF 219/556 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ADGRB2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 121/474 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ADH1C | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ADPRS | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 158/565 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ALG14 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 126/393 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.5593C>T p.P1865S | Missense Mutation (SNP) | VAF 172/359 reads (48%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKFN1 | c.1692G>A p.W564* | Nonsense Mutation (SNP) | VAF 92/350 reads (26%) | called by muse, mutect2, varscan2
- ANO3 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 116/422 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AOC3 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 173/538 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- APLP1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 138/502 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF10 | c.1652C>T p.P551L (on ENST00000398564; = p.P526L on NM_014629.4) | Missense Mutation (SNP) | VAF 162/581 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ARHGEF5 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 94/1272 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASAH2 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ASAP1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 202/512 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASXL3 | c.3692T>C p.F1231S | Missense Mutation (SNP) | VAF 157/464 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ATG101 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 166/552 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP11A | c.2015C>T p.T672I | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATP11C | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 115/493 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ATP1A1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 91/319 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ATP6V1C2 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 106/395 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AXL | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 102/299 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- BAZ1B | c.1427T>C p.L476P | Missense Mutation (SNP) | VAF 261/756 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAZ2A | c.3739T>C p.F1247L | Missense Mutation (SNP) | VAF 132/453 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPTF | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRSK2 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 85/395 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C12orf50 | c.401T>G p.I134S | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- C2CD3 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 107/463 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C3 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 101/394 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- C6orf58 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CACNA2D3 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 123/417 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CADPS2 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 277/765 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CADPS2 | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 171/523 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CARTPT | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 105/361 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CBLN3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 161/540 reads (30%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC160 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 150/571 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CCDC168 | c.17126G>A p.G5709E | Missense Mutation (SNP) | VAF 115/414 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC182 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 162/545 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCDC96 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 146/577 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- CCNA1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CDH24 | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 182/600 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH9 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 33/205 reads (16%) | called by muse, mutect2, varscan2
- CELSR1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 146/538 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELSR3 | c.7160C>T p.S2387F | Missense Mutation (SNP) | VAF 128/466 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- CEP57L1 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CFAP47 | c.3017G>A p.G1006E | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP54 | c.8608C>T p.P2870S | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CFAP92 | c.1501T>A p.Y501N | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFHR1 | c.429T>G p.T143= | Splice Region (SNP) | VAF 95/147 reads (65%) | called by muse, mutect2, varscan2
- CFHR5 | c.614T>A p.V205E | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CHRNA2 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 223/743 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHST8 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 203/658 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CLEC4M | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CNTN4 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 150/476 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, varscan2
- CNTNAP4 | c.3043C>T p.Q1015* | Nonsense Mutation (SNP) | VAF 54/153 reads (35%) | called by muse, mutect2, varscan2
- COL4A5 | c.4334G>A p.G1445E | Missense Mutation (SNP) | VAF 155/579 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ9 | c.341A>C p.H114P | Missense Mutation (SNP) | VAF 126/300 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CSF3 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 123/427 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CSMD1 | c.9659C>T p.P3220L (on ENST00000520002; = p.P3219L on NM_033225.6) | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD2 | c.637A>C p.I213L | Missense Mutation (SNP) | VAF 151/487 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CYRIA | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 118/388 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CYRIA | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 117/385 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DENND1A | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 128/425 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- DGKB | c.1434A>G p.P478= | Splice Region (SNP) | VAF 130/374 reads (35%) | called by muse, mutect2, varscan2
- DHX38 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DLGAP2 | c.2399G>A p.G800D | Missense Mutation (SNP) | VAF 230/750 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.3653G>A p.G1218E | Missense Mutation (SNP) | VAF 106/394 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DOCK10 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 89/284 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DRAXIN | c.642G>A p.Q214= | Splice Region (SNP) | VAF 80/276 reads (29%) | called by muse, mutect2, varscan2
- DRAXIN | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 126/414 reads (30%) | called by muse, mutect2, varscan2
- DST | c.17935A>T p.N5979Y (on ENST00000361203 / NM_001374722.1; = p.N3676Y on NM_015548.5) | Missense Mutation (SNP) | VAF 112/385 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- E2F1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 113/419 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ECPAS | c.3443C>T p.S1148F | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- EDEM3 | c.1582T>A p.C528S | Missense Mutation (SNP) | VAF 107/371 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF3L | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 102/397 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ELAVL2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ENAM | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 97/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ENPEP | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EPOR | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 177/567 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERCC6L | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 158/603 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EVI5 | c.2176C>T p.H726Y | Missense Mutation (SNP) | VAF 98/402 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FAM135A | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 111/335 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FAM186A | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 222/758 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FER1L6 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 171/412 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER1L6 | c.3685G>A p.E1229K | Missense Mutation (SNP) | VAF 190/453 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- FFAR1 | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 203/707 reads (29%) | called by muse, mutect2, varscan2
- FFAR4 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FKBP6 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 187/644 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMN2 | c.4318G>A p.E1440K | Missense Mutation (SNP) | VAF 93/290 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- FOXD4L1 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 233/826 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- FREM1 | c.6056G>A p.G2019E | Missense Mutation (SNP) | VAF 109/367 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRG2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 132/500 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FRMPD4 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 55/273 reads (20%) | called by muse, mutect2, varscan2
- GABRA2 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 116/447 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT9 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 146/492 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- GATM | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 102/361 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDPD4 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 107/432 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLGA8K | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 75/338 reads (22%) | called by muse, varscan2
- GPRC6A | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 149/479 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GREM1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 202/693 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GRIA3 | c.509-1G>A p.X170_splice | Splice Site (SNP) | VAF 104/316 reads (33%) | called by muse, mutect2, varscan2
- GRIN2A | c.3104A>G p.D1035G | Missense Mutation (SNP) | VAF 116/487 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GRIP1 | c.1511C>T p.S504F (on ENST00000359742 / NM_001379345.1; = p.S452F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/394 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- GRPEL2 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 63/231 reads (27%) | called by muse, mutect2, varscan2
- HCFC1 | c.4058C>T p.A1353V | Missense Mutation (SNP) | VAF 236/840 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRH1 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 153/516 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSD3B1 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 158/533 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTN3 | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HYDIN | c.13286C>T p.A4429V | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYDIN | c.6906G>A p.M2302I | Missense Mutation (SNP) | VAF 93/290 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ICAM5 | c.2222G>A p.G741D | Missense Mutation (SNP) | VAF 93/413 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IGBP1 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 192/650 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- IGFL2 | c.176C>T p.S59F (on ENST00000377693 / NM_001135113.2; = p.S70F on NM_001002915.2) | Missense Mutation (SNP) | VAF 131/496 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- IRS4 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 166/574 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA5 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 115/463 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KAT6B | c.1994A>G p.D665G | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KCNG4 | c.756G>A p.Q252= | Splice Region (SNP) | VAF 167/471 reads (35%) | called by muse, mutect2, varscan2
- KHDC4 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 153/548 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KIF26B | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 144/531 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIF26B | c.4811C>T p.S1604F | Missense Mutation (SNP) | VAF 247/853 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIN | c.361T>A p.W121R | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KL | c.2950G>A p.A984T | Missense Mutation (SNP) | VAF 89/349 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KMT2D | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 198/648 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRT17 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 108/420 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KRT6A | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 100/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KSR2 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 203/654 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.159); called by muse, mutect2
- LARS1 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 93/332 reads (28%) | called by muse, mutect2, varscan2
- LMTK2 | c.4025C>T p.P1342L | Missense Mutation (SNP) | VAF 332/873 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP5 | c.3701G>A p.G1234E | Missense Mutation (SNP) | VAF 134/443 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRC10B | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 180/653 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- LRRTM4 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 97/402 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP2K5 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAPK8IP2 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 193/628 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MARCHF4 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 194/636 reads (31%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MARS1 | c.309A>C p.L103F | Missense Mutation (SNP) | VAF 125/426 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MCM10 | c.2450C>T p.P817L (on ENST00000484800 / NM_182751.3; = p.P816L on NM_018518.5) | Missense Mutation (SNP) | VAF 111/276 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- MCTP1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 99/431 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MDFI | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 143/678 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MEAF6 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 134/530 reads (25%) | called by muse, mutect2, varscan2
- MEMO1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 83/407 reads (20%) | called by muse, mutect2, varscan2
- MINAR2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 92/347 reads (27%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- MMD | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 134/474 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP24 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 104/480 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPP4 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 78/313 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MROH2A | c.649A>C p.I217L | Missense Mutation (SNP) | VAF 110/447 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYH4 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2
- MYL5 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 97/351 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MYT1L | c.2119A>T p.S707C | Missense Mutation (SNP) | VAF 174/578 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- NFIL3 | c.402T>G p.Y134* | Nonsense Mutation (SNP) | VAF 105/377 reads (28%) | called by muse, mutect2, varscan2
- NOL9 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NOS1 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 106/385 reads (28%) | called by muse, mutect2, varscan2
- NOS2 | c.720C>T p.I240= | Splice Region (SNP) | VAF 109/373 reads (29%) | called by muse, mutect2, varscan2
- NRSN1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 166/500 reads (33%) | called by muse, varscan2
- NUP35 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 99/390 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- OR11H12 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 144/752 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, varscan2
- OR1E2 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 147/485 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2
- OR1J4 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 153/510 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR1P1 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.11); called by muse, mutect2
- OR2H2 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 104/632 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C6 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 151/470 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4P4 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 105/373 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR51I2 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 140/522 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2
- OR52N2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 102/321 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- OR5BS1P | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OR5H8 | c.701A>T p.H234L | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6K2 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 134/449 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OSR1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 166/542 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- OTOA | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OTUD7A | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 105/418 reads (25%) | called by muse, mutect2, varscan2
- PAMR1 | c.1795G>A p.A599T (on ENST00000619888 / NM_001001991.3; = p.A616T on NM_015430.4) | Missense Mutation (SNP) | VAF 188/654 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCARE | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 148/512 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PCDHGA7 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PCLO | c.13973G>A p.G4658E | Missense Mutation (SNP) | VAF 249/786 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PCLO | c.11411G>A p.G3804E | Missense Mutation (SNP) | VAF 271/795 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.3029C>T p.P1010L | Missense Mutation (SNP) | VAF 260/704 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PDE1B | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PDE1C | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 236/662 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); called by muse, varscan2
- PDE4DIP | c.5203C>T p.P1735S | Missense Mutation (SNP) | VAF 154/462 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- PEPD | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 123/518 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PGC | c.1082G>A p.W361* | Nonsense Mutation (SNP) | VAF 155/714 reads (22%) | called by muse, mutect2, varscan2
- PGD | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 58/311 reads (19%) | called by muse, mutect2, varscan2
- PHKA2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 116/379 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIEZO2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 129/414 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.621); called by muse, varscan2
- PIK3CA | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PKHD1L1 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 133/282 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PLA2G4C | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 119/457 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PLA2R1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 123/396 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLCH1 | c.4504G>A p.D1502N (on ENST00000340059 / NM_001130960.2; = p.D1494N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/371 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNPLA4 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 126/468 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- POC1A | c.1039A>G p.S347G | Missense Mutation (SNP) | VAF 147/524 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLA1 | c.4066C>T p.R1356* | Nonsense Mutation (SNP) | VAF 152/465 reads (33%) | called by muse, mutect2, varscan2
- PPP2R5B | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 150/560 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, varscan2
- PRAMEF1 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 161/528 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PRAMEF12 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 135/497 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PRAMEF5 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PRKD1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- PRL | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 78/525 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PRR23A | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 156/406 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRSS21 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 111/387 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PSG7 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 141/462 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PSME2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRD | c.5027T>C p.V1676A | Missense Mutation (SNP) | VAF 112/417 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PTPRK | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 186/587 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RAB2A | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RAD54L | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 85/380 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- RASAL3 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 183/584 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- RASSF4 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 129/295 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- RENBP | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, varscan2
- RIN3 | c.66A>C p.K22N | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RP1 | c.2831G>A p.R944K | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RP1 | c.4057G>A p.G1353R | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- RPGR | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 90/324 reads (28%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.928C>T p.H310Y (on ENST00000265814 / NM_001198628.1; = p.H283Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/586 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SCAF8 | c.2898_2901delinsTTG p.R967Wfs*18 | Frame Shift Del (DEL) | VAF 116/502 reads (23%) | called by pindel, varscan2*
- SCAPER | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 119/462 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCCPDH | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- SCYGR2 | c.127_128insTTGGTGGTGGCT p.G42_C43insFGGG | In Frame Ins (INS) | VAF 239/883 reads (27%) | called by mutect2, varscan2*
- SECTM1 | c.411A>C p.E137D | Missense Mutation (SNP) | VAF 103/339 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SELENBP1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 119/420 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SETD3 | c.247A>T p.M83L | Missense Mutation (SNP) | VAF 109/439 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD7 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 130/492 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK1 | c.6447G>A p.M2149I | Missense Mutation (SNP) | VAF 104/394 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLAMF7 | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 139/483 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SLC24A3 | c.1062G>A p.E354= | Splice Region (SNP) | VAF 75/272 reads (28%) | called by muse, mutect2, varscan2
- SLC26A3 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 175/464 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A15 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 132/487 reads (27%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC7A3 | c.1620+1G>A p.X540_splice | Splice Site (SNP) | VAF 94/249 reads (38%) | called by muse, mutect2, varscan2
- SORL1 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- SOWAHA | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 201/698 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- SPATA18 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 138/476 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SPOCD1 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 146/490 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- SRPX2 | c.1215C>T p.L405= | Splice Region (SNP) | VAF 63/218 reads (29%) | called by muse, mutect2, varscan2
- SSX7 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, varscan2
- STAB2 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 89/315 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STRA6 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SV2B | c.1125G>A p.W375* | Nonsense Mutation (SNP) | VAF 87/344 reads (25%) | called by muse, mutect2, varscan2
- SYTL1 | c.341-1G>A p.X114_splice | Splice Site (SNP) | VAF 94/339 reads (28%) | called by muse, mutect2, varscan2
- TANC2 | c.4693C>T p.Q1565* | Nonsense Mutation (SNP) | VAF 130/471 reads (28%) | called by muse, mutect2, varscan2
- TDRD1 | c.2954G>A p.S985N | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEX15 | c.2713G>A p.D905N (on ENST00000256246; = p.D1288N on NM_001350162.2) | Missense Mutation (SNP) | VAF 81/293 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- THRB | c.1090A>C p.N364H | Missense Mutation (SNP) | VAF 157/518 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- THSD1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 127/507 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMEM260 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 99/393 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- TNFSF15 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 138/543 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2
- TOPAZ1 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 142/560 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRAF7 | c.1687T>A p.Y563N | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV20 | c.51C>T p.G17= | Splice Region (SNP) | VAF 99/316 reads (31%) | called by muse, mutect2, varscan2
- TRAV25 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 112/341 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TRIM25 | c.1502T>G p.V501G | Missense Mutation (SNP) | VAF 156/530 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRIM49B | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 156/536 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TRPM3 | c.4855G>A p.E1619K (on ENST00000357533 / NM_001366142.2; = p.E1474K on NM_020952.6) | Missense Mutation (SNP) | VAF 130/484 reads (27%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TSHR | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 130/460 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TSHZ3 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 125/475 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TSPAN32 | c.280-1G>A p.X94_splice | Splice Site (SNP) | VAF 76/308 reads (25%) | called by muse, varscan2
- TSPAN6 | c.22_25del p.L8Rfs*14 | Frame Shift Del (DEL) | VAF 111/449 reads (25%) | called by mutect2, pindel, varscan2
- TUBA3D | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 140/651 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- TUBA8 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUT4 | c.4036C>T p.H1346Y | Missense Mutation (SNP) | VAF 187/624 reads (30%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TXK | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 117/417 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TXNDC9 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 88/402 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2
- UGT3A1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC80 | c.7933G>A p.V2645M | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USF1 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- USP26 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP28 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 134/501 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- USP29 | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 120/416 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP9X | c.7120C>T p.Q2374* | Nonsense Mutation (SNP) | VAF 118/509 reads (23%) | called by muse, mutect2, varscan2
- UTRN | c.5392G>A p.E1798K | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WDR35 | c.1513G>A p.D505N (on ENST00000345530 / NM_001006657.2; = p.D494N on NM_020779.4) | Missense Mutation (SNP) | VAF 78/342 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- WDR87 | c.8023C>T p.P2675S | Missense Mutation (SNP) | VAF 152/563 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- XIRP2 | c.1978G>A p.G660S (on ENST00000628543; = p.G835S on NM_152381.6) | Missense Mutation (SNP) | VAF 124/429 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.6646G>A p.D2216N (on ENST00000628543; = p.D2391N on NM_152381.6) | Missense Mutation (SNP) | VAF 150/534 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- XYLB | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZCCHC12 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 106/435 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMAT1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 161/547 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF160 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF208 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 120/475 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ZNF415 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 133/514 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ZNF460 | c.494A>T p.H165L | Missense Mutation (SNP) | VAF 129/428 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ZNF513 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 146/539 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ZNF595 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 126/438 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF597 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 130/439 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF70 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 161/565 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF700 | c.1660C>T p.H554Y | Missense Mutation (SNP) | VAF 172/584 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZSWIM5 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 129/432 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCB1 | c.3027C>T p.I1009= | Silent (SNP) | VAF 258/764 reads (34%) | called by muse, mutect2, varscan2
- ABCC9 | c.1023C>T p.T341= | Silent (SNP) | VAF 60/247 reads (24%) | called by muse, mutect2, varscan2
- AC024592.3 | c.231C>T p.L77= | Silent (SNP) | VAF 176/688 reads (26%) | catalogued as rs750966746; called by muse, mutect2, varscan2
- ADAMTS20 | c.5202T>A p.I1734= | Silent (SNP) | VAF 61/275 reads (22%) | called by muse, mutect2, varscan2
- ADGRB1 | c.3093C>T p.T1031= | Silent (SNP) | VAF 132/619 reads (21%) | catalogued as rs61756329; called by muse, mutect2, varscan2
- ADGRE1 | c.1164C>T p.S388= | Silent (SNP) | VAF 110/357 reads (31%) | called by muse, mutect2, varscan2
- ADGRG4 | c.495G>A p.K165= | Silent (SNP) | VAF 194/620 reads (31%) | called by muse, varscan2
- ADGRG4 | c.1194G>A p.T398= | Silent (SNP) | VAF 141/498 reads (28%) | catalogued as rs1250426983, COSV54966530; called by muse, mutect2, varscan2
- ADH1C | c.573C>T p.T191= | Silent (SNP) | VAF 103/378 reads (27%) | catalogued as COSV72463404; called by muse, mutect2, varscan2
- AFAP1L1 | c.204C>T p.F68= | Silent (SNP) | VAF 108/455 reads (24%) | catalogued as rs1167132674, COSV57044505; called by muse, mutect2, varscan2
- AKR1D1 | c.678G>A p.R226= | Silent (SNP) | VAF 142/401 reads (35%) | catalogued as rs745742597; called by muse, mutect2, varscan2
- ALK | c.1125C>T p.I375= | Silent (SNP) | VAF 122/412 reads (30%) | catalogued as COSV66566290; called by muse, mutect2, varscan2
- ALPK3 | c.3207C>T p.L1069= | Silent (SNP) | VAF 192/648 reads (30%) | catalogued as rs1336705405; called by muse, mutect2, varscan2
- AMIGO2 | c.1566T>C p.T522= | Silent (SNP) | VAF 65/207 reads (31%) | called by muse, mutect2, varscan2
- ANK3 | c.2976G>A p.A992= (on ENST00000280772 / NM_001320874.2; = p.A126= on NM_001149.3) | Silent (SNP) | VAF 106/279 reads (38%) | catalogued as rs747475542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD36B | c.1332G>T p.S444= | Silent (SNP) | VAF 66/309 reads (21%) | catalogued as COSV51532008; called by mutect2, varscan2
- ANOS1 | c.183C>T p.I61= | Silent (SNP) | VAF 139/479 reads (29%) | called by muse, mutect2, varscan2
- AQP8 | c.120C>T p.V40= | Silent (SNP) | VAF 122/435 reads (28%) | catalogued as rs371151656, COSV54847208; called by muse, mutect2, varscan2
- ARPC4 | c.363C>T p.F121= | Silent (SNP) | VAF 115/415 reads (28%) | called by muse, mutect2, varscan2
- ART3 | c.357G>A p.V119= | Silent (SNP) | VAF 161/531 reads (30%) | called by muse, mutect2, varscan2
- ASAP1 | c.1344C>T p.L448= | Silent (SNP) | VAF 206/517 reads (40%) | called by muse, mutect2, varscan2
- ATP8A1 | c.1032C>T p.F344= | Silent (SNP) | VAF 93/338 reads (28%) | called by muse, mutect2, varscan2
- ATP8B4 | c.1611C>T p.F537= | Silent (SNP) | VAF 83/308 reads (27%) | called by muse, mutect2, varscan2
- BCL9 | c.1773T>C p.S591= | Silent (SNP) | VAF 144/483 reads (30%) | called by muse, mutect2, varscan2
- BCL9L | c.573G>A p.L191= | Silent (SNP) | VAF 160/537 reads (30%) | catalogued as rs754579955; called by muse, mutect2, varscan2
- BIN1 | c.399C>T p.F133= | Silent (SNP) | VAF 92/288 reads (32%) | catalogued as rs755303195, COSV99388117; called by muse, mutect2, varscan2
- BUD23 | c.630C>T p.T210= | Silent (SNP) | VAF 275/769 reads (36%) | called by muse, mutect2, varscan2
- C10orf105 | c.298C>T p.L100= | Silent (SNP) | VAF 183/439 reads (42%) | called by muse, mutect2, varscan2
- C11orf87 | c.294G>A p.Q98= | Silent (SNP) | VAF 154/519 reads (30%) | called by muse, mutect2, varscan2
- C16orf72 | c.441G>T p.L147= | Silent (SNP) | VAF 127/446 reads (28%) | called by muse, mutect2, varscan2
- C2orf81 | c.1737C>T p.P579= | Silent (SNP) | VAF 113/369 reads (31%) | called by muse, mutect2, varscan2
- C3orf20 | c.1932C>T p.V644= | Silent (SNP) | VAF 84/304 reads (28%) | called by muse, mutect2, varscan2
- CABLES1 | c.1473C>T p.P491= (on ENST00000256925 / NM_001100619.2; = p.P226= on NM_138375.2) | Silent (SNP) | VAF 65/302 reads (22%) | catalogued as COSV56936527; called by muse, mutect2, varscan2
- CALCOCO1 | c.354C>T p.F118= | Silent (SNP) | VAF 147/519 reads (28%) | called by muse, mutect2, varscan2
- CAND2 | c.984G>A p.E328= (on ENST00000456430 / NM_001162499.2; = p.E235= on NM_012298.3) | Silent (SNP) | VAF 90/342 reads (26%) | catalogued as COSV55988796; called by muse, mutect2, varscan2
- CAPN10 | c.1443C>T p.F481= | Silent (SNP) | VAF 137/473 reads (29%) | catalogued as rs756668839, COSV54377853; called by muse, mutect2, varscan2
- CCDC124 | c.633C>T p.P211= | Silent (SNP) | VAF 91/385 reads (24%) | catalogued as rs966281855; called by muse, mutect2, varscan2
- CCDC125 | c.801G>A p.E267= | Silent (SNP) | VAF 93/402 reads (23%) | catalogued as COSV101143803; called by muse, mutect2, varscan2
- CCDC33 | c.378C>T p.I126= | Silent (SNP) | VAF 98/403 reads (24%) | called by muse, mutect2, varscan2
- CCSER1 | c.2034G>A p.S678= | Silent (SNP) | VAF 113/428 reads (26%) | catalogued as rs373571745, COSV100389979, COSV100397877; called by muse, mutect2, varscan2
- CD163 | c.2248C>T p.L750= | Silent (SNP) | VAF 135/498 reads (27%) | called by muse, mutect2, varscan2
- CDK9 | c.471C>T p.I157= | Silent (SNP) | VAF 130/428 reads (30%) | called by muse, mutect2, varscan2
- CFAP54 | c.6885C>T p.S2295= | Silent (SNP) | VAF 131/486 reads (27%) | catalogued as rs754108382; called by muse, mutect2, varscan2
- CFAP65 | c.2949G>A p.L983= | Silent (SNP) | VAF 128/492 reads (26%) | called by muse, mutect2, varscan2
- CFTR | c.384C>T p.C128= | Silent (SNP) | VAF 309/805 reads (38%) | catalogued as COSV50056961; called by muse, mutect2, varscan2
- CLU | c.1014C>T p.T338= | Silent (SNP) | VAF 116/416 reads (28%) | called by muse, mutect2, varscan2
- CMYA5 | c.1299C>T p.S433= | Silent (SNP) | VAF 131/484 reads (27%) | called by muse, mutect2, varscan2
- CNKSR1 | c.2112C>T p.S704= (on ENST00000374253 / NM_001297647.2; = p.S697= on NM_006314.3) | Silent (SNP) | VAF 151/583 reads (26%) | called by muse, mutect2, varscan2
- CNPY1 | c.195C>T p.A65= | Silent (SNP) | VAF 167/486 reads (34%) | called by muse, mutect2, varscan2
- CNTLN | c.2376C>T p.I792= | Silent (SNP) | VAF 117/436 reads (27%) | called by muse, mutect2, varscan2
- COL6A5 | c.2328G>A p.G776= | Silent (SNP) | VAF 121/258 reads (47%) | called by muse, mutect2, varscan2
- COL7A1 | c.7608G>A p.G2536= | Silent (SNP) | VAF 170/648 reads (26%) | called by muse, mutect2, varscan2
- COQ9 | c.342C>T p.H114= | Silent (SNP) | VAF 124/300 reads (41%) | catalogued as rs771763396, COSV99346024; ClinVar: likely benign; called by muse, mutect2, varscan2
- CREB5 | c.1137G>A p.R379= (on ENST00000357727 / NM_182898.4; = p.R372= on NM_004904.3) | Silent (SNP) | VAF 325/850 reads (38%) | called by muse, mutect2, varscan2
- CRYBG2 | c.4773C>T p.P1591= | Silent (SNP) | VAF 125/474 reads (26%) | called by muse, mutect2, varscan2
- CSMD1 | c.6831C>T p.F2277= (on ENST00000520002; = p.F2276= on NM_033225.6) | Silent (SNP) | VAF 97/354 reads (27%) | catalogued as rs371661443, COSV59378788; called by muse, mutect2
- CSMD2 | c.6631C>T p.L2211= | Silent (SNP) | VAF 124/532 reads (23%) | called by muse, mutect2, varscan2
- CYP2C19 | c.561C>T p.F187= | Silent (SNP) | VAF 115/296 reads (39%) | catalogued as rs895214411, COSV64906855; called by muse, mutect2, varscan2
- CYP4F11 | c.330C>T p.I110= | Silent (SNP) | VAF 87/272 reads (32%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.1122G>A p.V374= | Silent (SNP) | VAF 164/595 reads (28%) | called by muse, mutect2, varscan2
- DDX20 | c.438A>T p.I146= | Silent (SNP) | VAF 104/412 reads (25%) | called by muse, mutect2, varscan2
- DHX38 | c.834C>T p.A278= | Silent (SNP) | VAF 102/298 reads (34%) | catalogued as rs757149271; called by muse, mutect2, varscan2
- DISP1 | c.4068C>T p.F1356= | Silent (SNP) | VAF 147/468 reads (31%) | catalogued as rs767774464; called by muse, mutect2, varscan2
- DLGAP2 | c.1449C>T p.T483= | Silent (SNP) | VAF 104/423 reads (25%) | catalogued as rs746796732; called by muse, mutect2, varscan2
- DNAH3 | c.5328C>T p.F1776= | Silent (SNP) | VAF 139/451 reads (31%) | called by muse, mutect2, varscan2
- DNAH8 | c.8043C>T p.I2681= | Silent (SNP) | VAF 143/689 reads (21%) | called by muse, mutect2, varscan2
- DUSP4 | c.673C>T p.L225= | Silent (SNP) | VAF 150/462 reads (32%) | called by muse, mutect2, varscan2
- EFCAB8 | c.3717C>T p.S1239= | Silent (SNP) | VAF 142/478 reads (30%) | called by muse, mutect2, varscan2
- ELF3 | c.1023C>T p.I341= | Silent (SNP) | VAF 105/363 reads (29%) | called by muse, mutect2, varscan2
- ELFN2 | c.1074C>T p.T358= | Silent (SNP) | VAF 174/569 reads (31%) | called by muse, mutect2, varscan2
- EPPK1 | c.5817C>T p.F1939= | Silent (SNP) | VAF 194/741 reads (26%) | called by muse, mutect2, varscan2
- F2RL2 | c.360C>T p.F120= | Silent (SNP) | VAF 145/551 reads (26%) | catalogued as COSV56969659; called by muse, mutect2, varscan2
- F7 | c.723C>T p.T241= | Silent (SNP) | VAF 138/476 reads (29%) | called by muse, mutect2, varscan2
- FAH | c.564C>T p.P188= | Silent (SNP) | VAF 90/340 reads (26%) | catalogued as rs149988384; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM184A | c.510G>A p.R170= | Silent (SNP) | VAF 158/508 reads (31%) | called by muse, mutect2, varscan2
- FAM83B | c.1995C>T p.F665= | Silent (SNP) | VAF 104/388 reads (27%) | catalogued as COSV60919154; called by muse, mutect2, varscan2
- FER1L5 | c.618C>T p.N206= | Silent (SNP) | VAF 89/350 reads (25%) | called by muse, mutect2, varscan2
- FLNA | c.7797C>T p.T2599= (on ENST00000369850 / NM_001110556.2; = p.T2591= on NM_001456.3) | Silent (SNP) | VAF 176/604 reads (29%) | called by muse, mutect2, varscan2
- FLT3 | c.651G>A p.E217= | Silent (SNP) | VAF 58/263 reads (22%) | called by mutect2, varscan2
- FLYWCH1 | c.1842C>T p.S614= (on ENST00000253928 / NM_001308068.2; = p.S613= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 130/460 reads (28%) | called by muse, mutect2, varscan2
- FMNL2 | c.189G>A p.L63= | Silent (SNP) | VAF 81/325 reads (25%) | called by muse, mutect2, varscan2
- FN1 | c.1995C>T p.S665= | Silent (SNP) | VAF 82/321 reads (26%) | catalogued as rs374036795; called by muse, mutect2, varscan2
- FRAS1 | c.8775G>A p.K2925= | Silent (SNP) | VAF 95/322 reads (30%) | called by muse, mutect2, varscan2
- FRMPD2 | c.231T>C p.S77= | Silent (SNP) | VAF 125/284 reads (44%) | called by muse, mutect2, varscan2
- FRY | c.8571C>T p.S2857= | Silent (SNP) | VAF 68/307 reads (22%) | catalogued as COSV100969868; called by muse, mutect2, varscan2
- GATA3 | c.1263G>A p.P421= | Silent (SNP) | VAF 158/442 reads (36%) | catalogued as rs541782074, COSV60518783, COSV60519740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDPD4 | c.369G>A p.V123= | Silent (SNP) | VAF 70/337 reads (21%) | called by muse, mutect2, varscan2
- GEMIN5 | c.3258C>T p.S1086= | Silent (SNP) | VAF 151/557 reads (27%) | catalogued as rs752209577; called by muse, mutect2, varscan2
- GJA5 | c.327G>A p.R109= | Silent (SNP) | VAF 142/505 reads (28%) | catalogued as rs143695986, COSV54785289; called by muse, mutect2, varscan2
- GLP1R | c.363G>A p.R121= | Silent (SNP) | VAF 109/530 reads (21%) | called by muse, mutect2, varscan2
- GOLGA6D | c.1533G>A p.E511= | Silent (SNP) | VAF 52/474 reads (11%) | called by mutect2, varscan2
- GPR158 | c.1371G>A p.T457= | Silent (SNP) | VAF 89/224 reads (40%) | catalogued as rs1175352427, COSV100892907, COSV66264628; called by muse, mutect2, varscan2
- GPR50 | c.1641C>T p.I547= | Silent (SNP) | VAF 216/732 reads (30%) | called by muse, mutect2, varscan2
- GPRASP1 | c.57G>A p.G19= | Silent (SNP) | VAF 136/467 reads (29%) | called by muse, mutect2, varscan2
- GRIA3 | c.849C>T p.F283= | Silent (SNP) | VAF 146/494 reads (30%) | catalogued as COSV52070503; called by muse, mutect2, varscan2
- GSDMC | c.450G>A p.R150= | Silent (SNP) | VAF 256/580 reads (44%) | catalogued as COSV99415529; called by muse, mutect2, varscan2
- HCK | c.1326C>T p.S442= | Silent (SNP) | VAF 108/417 reads (26%) | called by muse, mutect2, varscan2
- HM13 | c.708C>T p.F236= | Silent (SNP) | VAF 112/397 reads (28%) | catalogued as rs746775043, COSV104409125; called by muse, mutect2, varscan2
- HSFX2 | c.87C>T p.F29= | Silent (SNP) | VAF 167/882 reads (19%) | called by muse, mutect2, varscan2
- HYDIN | c.11394G>A p.V3798= | Silent (SNP) | VAF 66/234 reads (28%) | catalogued as rs1196580927; called by muse, mutect2, varscan2
- HYDIN | c.1071G>A p.E357= | Silent (SNP) | VAF 62/266 reads (23%) | called by muse, mutect2
- IFNL3 | c.132C>T p.S44= | Silent (SNP) | VAF 154/544 reads (28%) | called by muse, mutect2, varscan2
- IGFN1 | c.2112C>T p.F704= (on ENST00000295591 / NM_001367841.1; = p.F3161= on NM_001164586.2) | Silent (SNP) | VAF 190/637 reads (30%) | called by muse, mutect2, varscan2
- IGKV1D-42 | c.207C>T p.F69= | Silent (SNP) | VAF 111/350 reads (32%) | catalogued as rs951463157; called by muse, mutect2, varscan2
- IL18RAP | c.1233C>T p.F411= | Silent (SNP) | VAF 119/372 reads (32%) | catalogued as rs140183707; called by muse, mutect2, varscan2
- INTU | c.690C>T p.V230= | Silent (SNP) | VAF 73/310 reads (24%) | called by muse, mutect2, varscan2
- IQSEC3 | c.828C>T p.A276= | Silent (SNP) | VAF 256/870 reads (29%) | called by muse, mutect2, varscan2
- ITGB4 | c.1209G>A p.G403= | Silent (SNP) | VAF 92/289 reads (32%) | catalogued as rs907459726; called by muse, mutect2, varscan2
- IZUMO3 | c.21C>T p.F7= | Silent (SNP) | VAF 114/350 reads (33%) | catalogued as rs1440894516; called by muse, mutect2, varscan2
- KAT6A | c.4374T>C p.S1458= | Silent (SNP) | VAF 157/510 reads (31%) | called by muse, mutect2, varscan2
- KCNB2 | c.1219C>T p.L407= | Silent (SNP) | VAF 117/484 reads (24%) | catalogued as rs1246954147, COSV73051477; called by muse, mutect2, varscan2
- KCNJ6 | c.990C>T p.I330= | Silent (SNP) | VAF 131/412 reads (32%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1290G>A p.G430= | Silent (SNP) | VAF 131/454 reads (29%) | called by muse, mutect2, varscan2
- KDM6B | c.255C>T p.P85= | Silent (SNP) | VAF 105/365 reads (29%) | called by muse, mutect2, varscan2
- KIF13A | c.3513C>T p.T1171= | Silent (SNP) | VAF 92/566 reads (16%) | catalogued as rs1159578575; called by muse, mutect2, varscan2
- KIF16B | c.2199C>T p.L733= | Silent (SNP) | VAF 103/386 reads (27%) | catalogued as COSV61704843; called by muse, mutect2, varscan2
- KIR3DL3 | c.666G>A p.G222= | Silent (SNP) | VAF 112/361 reads (31%) | called by muse, mutect2, varscan2
- KMT2D | c.3057C>T p.P1019= | Silent (SNP) | VAF 196/648 reads (30%) | called by muse, mutect2, varscan2
- KRT13 | c.1257C>T p.F419= | Silent (SNP) | VAF 115/424 reads (27%) | catalogued as COSV55840086; called by muse, mutect2, varscan2
- KRT3 | c.564C>T p.D188= | Silent (SNP) | VAF 127/514 reads (25%) | called by muse, mutect2, varscan2
- KRTAP19-3 | c.177C>T p.F59= | Silent (SNP) | VAF 166/563 reads (29%) | catalogued as rs199527602, COSV61854985; called by muse, mutect2, varscan2
- L1CAM | c.2340C>T p.T780= | Silent (SNP) | VAF 177/637 reads (28%) | catalogued as COSV100648928; called by muse, mutect2, varscan2
- LCN15 | c.531C>T p.N177= | Silent (SNP) | VAF 133/516 reads (26%) | called by muse, mutect2
- LCN2 | c.450G>A p.R150= | Silent (SNP) | VAF 94/357 reads (26%) | catalogued as rs1422426093; called by muse, mutect2, varscan2
- LINGO4 | c.1539C>T p.D513= | Silent (SNP) | VAF 158/507 reads (31%) | catalogued as rs1489497792; called by muse, mutect2, varscan2
- LPAR4 | c.492C>T p.I164= | Silent (SNP) | VAF 172/677 reads (25%) | catalogued as COSV70913264; called by muse, mutect2, varscan2
- LRRC8B | c.102C>T p.I34= | Silent (SNP) | VAF 151/520 reads (29%) | called by muse, mutect2, varscan2
- MAFK | c.210C>T p.I70= | Silent (SNP) | VAF 348/987 reads (35%) | catalogued as COSV52472928; called by muse, mutect2, varscan2
- MAGEB18 | c.897C>T p.F299= | Silent (SNP) | VAF 184/662 reads (28%) | catalogued as COSV57464250; called by muse, mutect2, varscan2
- MAGEC1 | c.2208C>T p.F736= | Silent (SNP) | VAF 186/710 reads (26%) | catalogued as COSV53576088; called by muse, mutect2, varscan2
- MAGEC3 | c.1785C>T p.I595= | Silent (SNP) | VAF 179/600 reads (30%) | catalogued as COSV68924092; called by muse, mutect2, varscan2
- MAGEE2 | c.375C>T p.F125= | Silent (SNP) | VAF 172/644 reads (27%) | catalogued as rs778905074; called by muse, mutect2, varscan2
- MANEAL | c.249C>T p.S83= | Silent (SNP) | VAF 86/289 reads (30%) | called by muse, mutect2, varscan2
- MATN2 | c.885G>A p.V295= | Silent (SNP) | VAF 141/633 reads (22%) | catalogued as rs756280812; called by muse, mutect2, varscan2
- MCHR2 | c.570C>T p.S190= | Silent (SNP) | VAF 74/306 reads (24%) | called by muse, mutect2, varscan2
- MED16 | c.2553C>T p.V851= | Silent (SNP) | VAF 181/565 reads (32%) | called by muse, mutect2, varscan2
- MGAT3 | c.1296C>T p.L432= | Silent (SNP) | VAF 162/560 reads (29%) | catalogued as rs145852869; called by muse, varscan2
- MORC2 | c.1491C>T p.I497= (on ENST00000397641 / NM_001303256.3; = p.I435= on NM_014941.3) | Silent (SNP) | VAF 95/362 reads (26%) | called by muse, mutect2
- MROH2B | c.2175C>T p.I725= | Silent (SNP) | VAF 89/363 reads (25%) | called by muse, mutect2, varscan2
- MTNR1B | c.342G>A p.K114= | Silent (SNP) | VAF 117/448 reads (26%) | catalogued as rs1565180910, COSV99925081; called by muse, mutect2, varscan2
- MUC16 | c.9147C>T p.T3049= | Silent (SNP) | VAF 94/370 reads (25%) | called by muse, mutect2, varscan2
- MUC22 | c.2274C>T p.A758= | Silent (SNP) | VAF 210/935 reads (22%) | called by muse, mutect2, varscan2
- MYADML2 | c.453C>T p.A151= | Silent (SNP) | VAF 196/660 reads (30%) | called by muse, mutect2, varscan2
- MYBPC3 | c.3523C>T p.L1175= | Silent (SNP) | VAF 126/451 reads (28%) | called by muse, mutect2, varscan2
- MYH11 | c.5649G>A p.K1883= | Silent (SNP) | VAF 139/543 reads (26%) | called by muse, mutect2, varscan2
- MYL5 | c.297C>T p.T99= | Silent (SNP) | VAF 98/355 reads (28%) | catalogued as rs567000230; called by muse, mutect2, varscan2
- MYO5B | c.4425G>A p.E1475= | Silent (SNP) | VAF 129/474 reads (27%) | called by muse, mutect2, varscan2
- NCKAP5 | c.4839G>A p.T1613= | Silent (SNP) | VAF 112/370 reads (30%) | catalogued as rs1178447718, COSV58426697; called by muse, mutect2, varscan2
- NCR2 | c.375C>T p.F125= | Silent (SNP) | VAF 103/504 reads (20%) | catalogued as rs1350435827; called by muse, mutect2, varscan2
- NFKBIL1 | c.936C>T p.A312= | Silent (SNP) | VAF 228/1044 reads (22%) | called by muse, mutect2, varscan2
- NHSL2 | c.855C>T p.S285= (on ENST00000510661; = p.S651= on NM_001013627.2) | Silent (SNP) | VAF 98/338 reads (29%) | called by muse, mutect2, varscan2
163 further variants in this file (0 protein-altering or splice-affecting, 130 silent, 33 other) are not listed here.
